Somatic mutation profile of tumor specimen d0511ea6-43c3-4c61-b08e-cf49b7 (aliquot d0511ea6-43c3-4c61-b08e-cf49b7_D6_1) from CPTAC case 27CO004, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC.
Specimen d0511ea6-43c3-4c61-b08e-cf49b7: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19d99fa6-fbfa-4c13-954f-63b0dce2ba4a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 445994d9-9fa5-478c-91b7-abc726 (Blood Derived Normal), aliquot 445994d9-9fa5-478c-91b7-abc726_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db09bf7d-4fbb-4233-a031-aac828c7eeff

The open-access MAF lists 135 somatic variants for this specimen: 90 protein-altering or splice-affecting, 33 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 33, Intron 6, Nonsense Mutation 5, Frame Shift Ins 2, 5'UTR 2, Splice Site 2, Splice Region 2, 3'Flank 2, 3'UTR 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V1A | c.80C>G p.P27R | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553709380; ClinVar: pathogenic; called by muse, mutect2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 79/270 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS7 | c.3575G>A p.S1192N | Missense Mutation (SNP) | VAF 74/264 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs560063749; called by muse, mutect2, varscan2
- ADCY10 | c.2764G>A p.E922K | Missense Mutation (SNP) | VAF 91/396 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs772519958; called by muse, mutect2, varscan2
- ASTN1 | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as rs750249282, COSV56061957, COSV56086029; called by muse, mutect2, varscan2
- ASXL1 | c.1696G>T p.E566* | Nonsense Mutation (SNP) | VAF 49/220 reads (22%) | catalogued as COSV100038917; called by muse, mutect2, varscan2
- CCDC88B | c.2782C>T p.Q928* | Nonsense Mutation (SNP) | VAF 35/152 reads (23%) | catalogued as rs1249653787; called by muse, mutect2, varscan2
- CERT1 | c.1505G>A p.R502H (on ENST00000405807 / NM_001130105.1; = p.R374H on NM_005713.3) | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs753345726, COSV54663043; called by muse, mutect2, varscan2
- CFAP54 | c.7279G>A p.A2427T | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.65); catalogued as rs758706208, COSV61574326; called by muse, mutect2, varscan2
- CNKSR2 | c.664A>G p.K222E | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as rs772738879, COSV54254532; called by muse, mutect2, varscan2
- COL27A1 | c.3879G>A p.T1293= | Splice Region (SNP) | VAF 11/43 reads (26%) | catalogued as rs1051346980; called by muse, mutect2, varscan2
- CPNE7 | c.656C>T p.T219M | Missense Mutation (SNP) | VAF 51/197 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as rs764831303; called by muse, mutect2, varscan2
- DNAH11 | c.7138C>G p.L2380V | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1562508382; called by muse, mutect2, varscan2
- DNAJB11 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV54003639; called by muse, mutect2
- DPYSL2 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs143980725; called by muse, mutect2, varscan2
- FAM181B | c.1250C>T p.A417V | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs762797798; called by muse, mutect2, varscan2
- FBN1 | c.1949G>A p.R650H | Missense Mutation (SNP) | VAF 56/200 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1437690192, COSV57317478; called by muse, mutect2, varscan2
- FLRT2 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.198); catalogued as rs201758646; called by muse, mutect2, varscan2
- FRYL | c.4028T>C p.L1343P | Missense Mutation (SNP) | VAF 49/245 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.072); catalogued as COSV51949295; called by muse, mutect2, varscan2
- HELB | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs1042772360; called by muse, mutect2, varscan2
- HLA-B | c.343+5G>C | Splice Region (SNP) | VAF 82/275 reads (30%) | catalogued as rs747868714; called by muse, mutect2
- IL1RAPL2 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.248); catalogued as rs1298370119, COSV61158149; called by muse, mutect2, varscan2
- JAK1 | c.2331G>T p.W777C | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100692611, COSV61088158; called by mutect2, varscan2
- KANK2 | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 81/247 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs746234296; called by muse, mutect2, varscan2
- KCNT1 | c.1496C>T p.A499V (on ENST00000488444; = p.A518V on NM_020822.3) | Missense Mutation (SNP) | VAF 59/231 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs751063680; called by muse, mutect2, varscan2
- KIF4B | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 55/242 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs199820075, COSV101469192, COSV70526998; called by muse, mutect2, varscan2
- KRTAP24-1 | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV61088971; called by muse, mutect2, varscan2
- LEPR | c.3268_3269dup p.S1090Rfs*6 | Frame Shift Ins (INS) | VAF 42/120 reads (35%) | catalogued as rs1553174844; called by mutect2, varscan2
- LRRC4 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 147/497 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.298); catalogued as rs781397665; called by muse, mutect2, varscan2
- MED26 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 69/266 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as rs551219804; called by muse, mutect2, varscan2
- MOGS | c.1610C>G p.A537G | Missense Mutation (SNP) | VAF 20/444 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV99270564; called by muse, mutect2
- MUC16 | c.28318T>A p.S9440T | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.054); catalogued as rs758757464; called by muse, mutect2, varscan2
- MYCBP2 | c.10850G>A p.R3617H (on ENST00000357337; = p.R3655H on NM_015057.5) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.379); catalogued as rs373027753; called by muse, mutect2, varscan2
- NEURL1B | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.608); catalogued as COSV63940025; called by muse, varscan2
- NSD1 | c.5932G>A p.E1978K | Missense Mutation (SNP) | VAF 72/231 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV61771534; called by muse, mutect2, varscan2
- OBSCN | c.19358C>T p.P6453L | Missense Mutation (SNP) | VAF 72/310 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs376822169, COSV100804973; called by muse, mutect2, varscan2
- PCDHB4 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99521837; called by muse, mutect2, varscan2
- PCDHGC5 | c.1438G>T p.D480Y | Missense Mutation (SNP) | VAF 12/337 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52769269; called by muse, mutect2
- PPP4R4 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs745732168, COSV58553728; called by muse, mutect2
- PRRG3 | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 45/170 reads (26%) | catalogued as rs765253591; called by muse, mutect2, varscan2
- PSG7 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 73/260 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs376395338; called by muse, mutect2, varscan2
- RECQL5 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs757624935; called by muse, varscan2
- RTP5 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.216); catalogued as rs763603406, COSV58322447; called by muse, mutect2, varscan2
- SHROOM2 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1445822199; called by muse, varscan2
- SND1 | c.1774C>T p.R592* | Nonsense Mutation (SNP) | VAF 30/114 reads (26%) | catalogued as COSV61243047; called by muse, mutect2, varscan2
- SPTBN5 | c.710A>G p.N237S | Missense Mutation (SNP) | VAF 142/516 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1348151819; called by muse, mutect2, varscan2
- SRFBP1 | c.707dup p.N236Kfs*5 | Frame Shift Ins (INS) | VAF 17/84 reads (20%) | catalogued as rs751748506; called by mutect2, varscan2
- TEX14 | c.3281C>A p.S1094* (on ENST00000240361 / NM_001201457.2; = p.S1088* on NM_198393.4) | Nonsense Mutation (SNP) | VAF 40/111 reads (36%) | catalogued as COSV53611227; called by muse, mutect2, varscan2
- TRIM46 | c.1519C>T p.R507C | Missense Mutation (SNP) | VAF 52/189 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1366009172, COSV58112397; called by muse, mutect2, varscan2
- TTLL4 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs747956757; called by muse, mutect2
- TXNRD2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 15/50 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs749057584; called by muse, mutect2, varscan2
- UNC5D | c.2381G>A p.R794H | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1240940953, COSV54820217; called by mutect2, varscan2
- VASH2 | c.754G>A p.V252I (on ENST00000517399 / NM_001301056.2; = p.V208I on NM_024749.5) | Missense Mutation (SNP) | VAF 40/211 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.426); catalogued as rs547668925, COSV55118677, COSV99663745; called by muse, mutect2, varscan2
- ZNF33B | c.1796A>G p.H599R | Missense Mutation (SNP) | VAF 63/251 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs139019633; called by muse, mutect2, varscan2
- ZNF518B | c.2726G>A p.R909H | Missense Mutation (SNP) | VAF 69/236 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs774635179, COSV100456852; called by muse, mutect2, varscan2
- ABLIM2 | c.822+1G>C p.X274_splice | Splice Site (SNP) | VAF 19/199 reads (10%) | called by muse, mutect2, varscan2
- AKAP3 | c.143A>G p.D48G | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ARL4A | c.37T>C p.S13P | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.015); called by mutect2, varscan2
- ATG16L2 | c.1004A>T p.H335L | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CANX | c.1439G>T p.R480L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.326); called by mutect2, varscan2
- EEF1A1 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 44/247 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ENTPD7 | c.262G>C p.V88L | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- ESPNL | c.458T>C p.L153P | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GGCT | c.85G>C p.E29Q | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- GNA15 | c.440G>C p.C147S | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by mutect2, varscan2
- HDAC8 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- JAK2 | c.2198C>G p.A733G | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KCNQ5 | c.887C>A p.S296Y | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- KIF27 | c.1061A>C p.D354A | Missense Mutation (SNP) | VAF 59/244 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- KIF4A | c.1072-2A>G p.X358_splice | Splice Site (SNP) | VAF 27/105 reads (26%) | called by muse, mutect2, varscan2
- LILRB3 | c.95G>C p.W32S | Missense Mutation (SNP) | VAF 105/607 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.206); called by muse, varscan2
- MARCHF7 | c.1160C>T p.S387F | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MGAT4B | c.390G>C p.Q130H | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.77); called by muse, mutect2
- MORC4 | c.2618C>T p.A873V | Missense Mutation (SNP) | VAF 51/216 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2
- MYH15 | c.3387_3399del p.L1130* | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel, varscan2
- NHLRC3 | c.981T>G p.I327M | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- OCRL | c.6G>C p.E2D | Missense Mutation (SNP) | VAF 68/218 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR2T12 | c.920T>C p.V307A | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OSBPL2 | c.25G>C p.D9H | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PAIP1 | c.1307A>G p.Y436C | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PAXIP1 | c.792A>C p.L264F | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- RFX1 | c.1748T>A p.L583H | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SNX4 | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.066); called by muse, mutect2
- SORT1 | c.1052A>T p.Y351F | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- SPIDR | c.325T>C p.S109P | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- STRAP | c.605A>T p.Y202F | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- SUGP1 | c.1616A>T p.E539V | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TBX3 | c.826A>C p.T276P (on ENST00000257566 / NM_016569.4; = p.T256P on NM_005996.4) | Missense Mutation (SNP) | VAF 74/301 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- THOC2 | c.2957G>T p.C986F | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF577 | c.753C>G p.F251L | Missense Mutation (SNP) | VAF 67/303 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AATK | c.820C>T p.L274= (on ENST00000326724 / NM_001080395.3; = p.L171= on NM_004920.2) | Silent (SNP) | VAF 31/160 reads (19%) | called by muse, mutect2, varscan2
- ANKRD24 | c.1413C>T p.D471= | Silent (SNP) | VAF 34/124 reads (27%) | catalogued as rs369581994; called by muse, mutect2, varscan2
- ANKRD27 | c.2397G>T p.S799= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs752094955, COSV60129263; called by muse, mutect2, varscan2
- APCDD1L | c.459C>T p.R153= | Silent (SNP) | VAF 47/119 reads (39%) | catalogued as COSV64488049; called by muse, mutect2, varscan2
- BEND7 | c.1386C>T p.H462= | Silent (SNP) | VAF 36/153 reads (24%) | catalogued as rs367878278; called by muse, mutect2, varscan2
- CCDC120 | c.1443C>T p.L481= | Silent (SNP) | VAF 50/189 reads (26%) | called by muse, mutect2, varscan2
- CPPED1 | c.177C>T p.D59= | Silent (SNP) | VAF 49/186 reads (26%) | catalogued as rs779150099; called by muse, mutect2, varscan2
- CSF1R | c.2112C>T p.L704= | Silent (SNP) | VAF 49/195 reads (25%) | catalogued as rs147072380, COSV53827588; called by muse, mutect2, varscan2
- CWF19L1 | c.369A>G p.V123= | Silent (SNP) | VAF 16/199 reads (8%) | catalogued as COSV100821508; called by muse, mutect2
- EP300 | c.4917G>A p.L1639= | Silent (SNP) | VAF 111/300 reads (37%) | called by muse, mutect2, varscan2
- EP400 | c.1911G>A p.Q637= | Silent (SNP) | VAF 28/85 reads (33%) | called by muse, mutect2, varscan2
- EVX1 | c.489C>T p.N163= | Silent (SNP) | VAF 91/314 reads (29%) | catalogued as rs758099155; called by muse, mutect2, varscan2
- FRMD6 | c.1158C>T p.T386= (on ENST00000344768 / NM_001267046.2; = p.T378= on NM_152330.4) | Silent (SNP) | VAF 49/209 reads (23%) | catalogued as rs781001684; called by muse, mutect2, varscan2
- GOLGA4 | c.2907G>A p.T969= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs573440046; called by muse, mutect2, varscan2
- GRM6 | c.1764G>A p.P588= | Silent (SNP) | VAF 74/285 reads (26%) | catalogued as rs138980304; called by muse, mutect2, varscan2
- HCN1 | c.243C>T p.F81= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV57495240; called by muse, varscan2
- HCRTR2 | c.150G>A p.P50= | Silent (SNP) | VAF 110/459 reads (24%) | catalogued as COSV63794950; called by muse, mutect2, varscan2
- IGSF5 | c.1017C>T p.S339= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as rs370289405, COSV101011991; called by muse, mutect2, varscan2
- KRTAP23-1 | c.84C>A p.G28= | Silent (SNP) | VAF 22/522 reads (4%) | called by muse, mutect2
- MAGEE1 | c.132C>T p.D44= | Silent (SNP) | VAF 67/296 reads (23%) | catalogued as rs1556839112; called by muse, mutect2, varscan2
- MLYCD | c.1101A>T p.T367= | Silent (SNP) | VAF 12/341 reads (4%) | called by muse, mutect2
- MYO7A | c.351G>A p.E117= | Silent (SNP) | VAF 44/194 reads (23%) | called by mutect2, varscan2
- NGFR | c.225C>T p.D75= | Silent (SNP) | VAF 40/125 reads (32%) | catalogued as rs1472814572, COSV99412701; called by muse, mutect2, varscan2
- OVOL2 | c.648C>T p.C216= | Silent (SNP) | VAF 71/191 reads (37%) | catalogued as rs543562187; called by muse, mutect2, varscan2
- PANK2 | c.1368G>T p.G456= (on ENST00000316562 / NM_153638.3; = p.G165= on NM_024960.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 61/179 reads (34%) | called by muse, mutect2, varscan2
- PCDHB5 | c.1569G>A p.L523= | Silent (SNP) | VAF 31/842 reads (4%) | catalogued as COSV50647134; called by muse, mutect2
- PLCG2 | c.1860G>A p.T620= | Silent (SNP) | VAF 107/436 reads (25%) | catalogued as rs751368408; called by mutect2, varscan2
- SCAF1 | c.915C>T p.Y305= | Silent (SNP) | VAF 39/135 reads (29%) | catalogued as rs758759965, COSV100862168; called by muse, mutect2, varscan2
- SLC36A3 | c.1299C>T p.I433= | Silent (SNP) | VAF 76/300 reads (25%) | catalogued as COSV58857956; called by muse, mutect2, varscan2
- SPATA31E1 | c.2130C>T p.S710= | Silent (SNP) | VAF 76/307 reads (25%) | catalogued as rs576427799; called by muse, mutect2, varscan2
- STX1A | c.591G>A p.T197= | Silent (SNP) | VAF 34/150 reads (23%) | catalogued as rs782245623; called by mutect2, varscan2
- TSGA10 | c.789C>G p.L263= | Silent (SNP) | VAF 14/69 reads (20%) | called by muse, mutect2, varscan2
- WDR72 | c.1410A>G p.P470= | Silent (SNP) | VAF 22/108 reads (20%) | called by muse, mutect2, varscan2
- ARHGEF25 | chr12:57621284 C>A | 3'Flank (SNP) | VAF 20/84 reads (24%) | called by muse, varscan2
- C19orf71 | chr19:3538782 G>C | 5'Flank (SNP) | VAF 9/181 reads (5%) | called by muse, mutect2
- CCDC13 | c.603+2001G>A | Intron (SNP) | VAF 30/141 reads (21%) | catalogued as rs1232176544; called by muse, mutect2, varscan2
- COL4A2 | c.1340-141C>T | Intron (SNP) | VAF 43/170 reads (25%) | called by mutect2, varscan2
- ERCC6 | c.1397+8224C>T | Intron (SNP) | VAF 49/285 reads (17%) | catalogued as rs377759740; called by muse, mutect2, varscan2
- GIPR | c.855-48del | Intron (DEL) | VAF 78/263 reads (30%) | called by mutect2, pindel, varscan2
- GTF2A1L | c.-15G>T | 5'UTR (SNP) | VAF 23/109 reads (21%) | called by muse, mutect2, varscan2
- LRPPRC | c.*33T>G | 3'UTR (SNP) | VAF 42/109 reads (39%) | called by muse, mutect2, varscan2
- PAGE5 | c.-55G>A | 5'UTR (SNP) | VAF 37/181 reads (20%) | catalogued as rs761883603, COSV56943029, COSV99215679; called by muse, mutect2, varscan2
- PRDM11 | chr11:45227726 G>A | 3'Flank (SNP) | VAF 61/218 reads (28%) | catalogued as rs1432683092; called by muse, mutect2
- RPL32 | c.97-31C>T | Intron (SNP) | VAF 39/163 reads (24%) | catalogued as rs369052575, COSV55993319; called by muse, mutect2, varscan2
- ZNF692 | c.211+22del | Intron (DEL) | VAF 32/152 reads (21%) | called by mutect2, pindel, varscan2
